Somatic mutation profile of tumor specimen 0DVSBY from CCDI case PBCNCW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.0 years (722 days).
Specimen 0DVSBY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1f4db4b-e904-46c6-aceb-e28a8e5135e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVSCC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1180c0d2-2cb2-47bc-a413-c974552c99f0

The open-access MAF lists 3 somatic variants for this specimen: 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FES | c.819C>T p.D273= | Silent (SNP) | VAF 39/163 reads (24%) | catalogued as rs764804705; called by muse, varscan2
- NAV2 | c.2973G>T p.V991= (on ENST00000396087 / NM_001244963.2; = p.V968= on NM_145117.5) | Silent (SNP) | VAF 46/188 reads (24%) | called by muse, varscan2
- ANO6 | c.-37C>T | 5'UTR (SNP) | VAF 22/140 reads (16%) | catalogued as rs1446577374; called by muse, varscan2
